Somatic mutation profile of tumor specimen TCGA-EY-A1GQ-01A (aliquot TCGA-EY-A1GQ-01A-21D-A13L-09) from TCGA case TCGA-EY-A1GQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 76.4 years (27,905 days).
Specimen TCGA-EY-A1GQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71f20108-6f29-4d48-a7bb-6eb1a505a065.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GQ-10A (Blood Derived Normal), aliquot TCGA-EY-A1GQ-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b7f6379-b864-4c2e-8b37-3ae5f125e7a7

The open-access MAF lists 572 somatic variants for this specimen: 423 protein-altering or splice-affecting, 132 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 295, Silent 132, Frame Shift Del 72, Frame Shift Ins 24, Nonsense Mutation 11, Splice Site 8, Intron 7, Splice Region 6, In Frame Del 5, 5'UTR 4, 3'UTR 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- ACVR1 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906589, CM091421, COSV55115990, COSV55115998; ClinVar: likely pathogenic / other; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 16/94 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLI1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773148506, CM1511325, COSV55648982; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1723_1731del p.K575_R577del (on ENST00000521381 / NM_181523.3; = p.K305_R307del on NM_181504.4) | In Frame Del (DEL) | VAF 16/56 reads (29%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 91/145 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AARS2 | c.1845G>T p.Q615H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99771280; called by muse, mutect2, varscan2
- AASDH | c.2493T>G p.C831W | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99220882; called by muse, mutect2, varscan2
- ABCA9 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs892351153, COSV100382713, COSV60625057; called by muse, mutect2, varscan2
- ABCG2 | c.1654dup p.S552Ffs*33 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | catalogued as rs1281244555; called by mutect2, pindel, varscan2
- AC092143.1 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs777490310, COSV100205539; called by muse, mutect2, varscan2
- ACAD11 | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99391652; called by muse, mutect2, varscan2
- ACVRL1 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs760773605, COSV101187793; called by muse, mutect2, varscan2
- ADAM12 | c.1801A>G p.I601V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100900106; called by muse, mutect2, varscan2
- ADAMTS19 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV99176461; called by muse, mutect2, varscan2
- ADGRA2 | c.2365A>G p.I789V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV99604723; called by muse, mutect2, varscan2
- ADGRB1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs761798550, COSV60098853; called by muse, mutect2, varscan2
- AGK | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100814547, COSV100814743; called by muse, mutect2, varscan2
- AGTPBP1 | c.3342+2T>C p.X1114_splice (on ENST00000357081 / NM_001330701.2; = p.X1074_splice on NM_015239.2) | Splice Site (SNP) | VAF 35/91 reads (38%) | catalogued as rs1459205000, COSV100429331; called by muse, mutect2, varscan2
- AHCTF1 | c.2792del p.L931Cfs*8 (on ENST00000366508; = p.L905Cfs*8 on NM_015446.5) | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as rs1558240077, COSV58245421; called by mutect2, pindel
- AHNAK2 | c.7546G>A p.D2516N | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as rs755020096, COSV60922838; called by muse, mutect2, varscan2
- ALPL | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100876798; called by muse, mutect2, varscan2
- AMOTL1 | c.1186T>C p.S396P | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100504222; called by muse, mutect2, varscan2
- ANKIB1 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99728491; called by muse, mutect2, varscan2
- ANKRD22 | c.21+2T>C p.X7_splice | Splice Site (SNP) | VAF 30/88 reads (34%) | catalogued as COSV100905450; called by muse, mutect2, varscan2
- ARHGAP31 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99956662; called by muse, mutect2
- ARID2 | c.298T>A p.Y100N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100535519; called by muse, mutect2, varscan2
- ATAT1 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99457569; called by muse, mutect2, varscan2
- ATAT1 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV52541972; called by muse, mutect2, varscan2
- ATP2B1 | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99665259; called by muse, mutect2, varscan2
- ATP6AP1 | c.1202A>G p.Q401R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100870655; called by muse, mutect2, varscan2
- ATP8B2 | c.2087T>C p.L696P (on ENST00000672630; = p.L663P on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527688; called by muse, mutect2, varscan2
- AXL | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV99996012; called by muse, mutect2, varscan2
- BAHCC1 | c.4413A>T p.R1471S | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV100311220; called by muse, mutect2, varscan2
- BCAN | c.441C>A p.S147R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); catalogued as COSV100227902; called by muse, mutect2, varscan2
- BCL9 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99324507, COSV99324562; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BDP1 | c.2648C>T p.S883F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV100702777; called by mutect2, varscan2
- BICD1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as rs907706694, COSV99862025; called by muse, mutect2, varscan2
- BICRAL | c.2851A>G p.T951A | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1035281466, COSV100017866; called by muse, mutect2, varscan2
- BIRC2 | c.404T>G p.F135C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1412020397, COSV99926549; called by muse, mutect2, varscan2
- C3orf20 | c.2666G>A p.S889N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.011); catalogued as COSV53789851; called by muse, mutect2
- C6orf15 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs780449865, COSV99456672; called by muse, mutect2, varscan2
- CACNA1S | c.5213C>A p.P1738H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV100754710; called by muse, mutect2, varscan2
- CALCOCO1 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752477440, COSV100017180; called by muse, mutect2, varscan2
- CAMKK2 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100242646; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA2 | c.2474T>C p.L825P | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99236228; called by muse, mutect2
- CAPZA2 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753838; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as rs1256378164; called by mutect2, pindel, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs756347761; called by mutect2, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | catalogued as rs1276928429, COSV55666935; called by mutect2, pindel, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 53/110 reads (48%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDC40 | c.416T>C p.L139S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.325); catalogued as COSV57010052; called by muse, mutect2, varscan2
- CELSR2 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs938856010, COSV99603183; called by muse, mutect2, varscan2
- CEP152 | c.3139C>A p.L1047M | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100358563; called by muse, mutect2, varscan2
- CHAF1A | c.967A>G p.K323E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV100010888; called by muse, mutect2, varscan2
- CHAF1B | c.757+2T>C p.X253_splice | Splice Site (SNP) | VAF 25/69 reads (36%) | catalogued as COSV100023373; called by muse, mutect2, varscan2
- CHD5 | c.4260+2T>C p.X1420_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99312664; called by muse, mutect2, varscan2
- CHERP | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs368216200; called by muse, mutect2, varscan2
- CHST5 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as rs549820447, COSV100291767; called by muse, mutect2, varscan2
- CILP | c.2585C>T p.T862M | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs746197365, COSV99972894; called by muse, mutect2, varscan2
- CIRBP | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1215211863, COSV58011863; called by muse, varscan2
- CLCN3 | c.2246T>C p.L749S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100641602; called by muse, mutect2, varscan2
- CLDN16 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV99289988, COSV99289996; called by muse, mutect2, varscan2
- CLEC4G | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs1294612150, COSV61003413; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs369752219; called by mutect2, varscan2
- CNGA1 | c.761T>C p.L254S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100652141; called by muse, mutect2
- CNTNAP1 | c.129C>G p.Y43* | Nonsense Mutation (SNP) | VAF 39/106 reads (37%) | catalogued as COSV99226159; called by muse, mutect2
- CNTNAP2 | c.2204A>G p.N735S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV100663328; called by muse, mutect2, varscan2
- COL3A1 | c.1347C>T p.R449= | Splice Region (SNP) | VAF 10/34 reads (29%) | catalogued as rs755731385, COSV100482599; ClinVar: benign; called by muse, mutect2, varscan2
- COL5A1 | c.2981G>C p.G994A | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65670664; called by muse, mutect2, varscan2
- COL9A2 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs901545048, COSV101028392; called by muse, mutect2, varscan2
- CORIN | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99903039; called by muse, mutect2, varscan2
- CPT1A | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs368052217; called by muse, mutect2, varscan2
- CR1 | c.3671A>G p.Y1224C | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100887415; called by muse, mutect2, varscan2
- CR1L | c.1348T>G p.S450A | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99686870; called by muse, mutect2
- CSMD3 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52360141; called by muse, mutect2, varscan2
- CTBP2 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100456180; called by muse, mutect2, varscan2
- CTCF | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99864516; called by muse, mutect2
- CTIF | c.264A>C p.K88N | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); catalogued as COSV99836937; called by muse, mutect2, varscan2
- CTNNA1 | c.46A>G p.K16E | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as rs759641978, COSV100242243; called by muse, mutect2, varscan2
- CTNND1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100649850; called by muse, mutect2, varscan2
- CTU1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs979073206, COSV101361795; called by muse, mutect2, varscan2
- CUL4B | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100340209; called by muse, mutect2
- CXXC1 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs1384436252, COSV99495608; called by muse, mutect2, varscan2
- CYLC1 | c.1690A>G p.T564A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as rs757311616, COSV100254138; called by muse, mutect2, varscan2
- CYP7B1 | c.968A>T p.D323V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as COSV100040962; called by muse, mutect2, varscan2
- DCAF8L1 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 28/104 reads (27%) | catalogued as rs61735181, COSV71595386; called by muse, mutect2, varscan2
- DCBLD1 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780427862, COSV51646948; called by muse, mutect2, varscan2
- DDX42 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100834842, COSV63790191; called by muse, mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as rs772416332; called by mutect2, varscan2
- DHX37 | c.2647A>G p.K883E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100439034; called by muse, mutect2, varscan2
- DHX8 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs146727331; called by muse, mutect2, varscan2
- DIDO1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV99824966; called by muse, mutect2, varscan2
- DISP3 | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.087); catalogued as rs757088901, COSV53821410, COSV53826191; called by muse, mutect2, varscan2
- DLL1 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370005717, COSV64537445; called by muse, mutect2, varscan2
- DNAH10 | c.7879G>T p.G2627C (on ENST00000409039; = p.G2566C on NM_207437.3) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.873); catalogued as COSV101292036; called by muse, mutect2, varscan2
- DNAH7 | c.11996C>T p.A3999V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as COSV100414094; called by muse, mutect2, varscan2
- DNAI2 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs776802277, COSV56761251; called by muse, mutect2, varscan2
- DNHD1 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs144649403; called by muse, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK9 | c.5750G>A p.R1917Q (on ENST00000376460 / NM_001366676.2; = p.R1918Q on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1339473777, COSV100238133; called by muse, mutect2, varscan2
- DOT1L | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.229); catalogued as rs369996787; called by mutect2, varscan2
- DPY19L2 | c.2275T>C p.*759Rext*25 | Nonstop Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100192879; called by muse, mutect2
- DUSP5 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs371109451; called by muse, mutect2, varscan2
- EGFLAM | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as rs200790571, COSV59303445, COSV59310220; called by muse, mutect2, varscan2
- EGR4 | c.910T>A p.F304I (on ENST00000545030; = p.F201I on NM_001965.4) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV101474213; called by muse, mutect2, varscan2
- EP300 | c.3325G>A p.G1109R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54325990, COSV99607253; called by muse, mutect2, varscan2
- EPHB6 | c.760del p.A254Pfs*21 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs756241644, COSV67420943; called by mutect2, pindel, varscan2
- EPPK1 | c.2005A>G p.R669G | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV101599752; called by muse, mutect2, varscan2
- EPX | c.1567A>G p.M523V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.272); catalogued as rs1177158094, COSV99836284; called by muse, mutect2, varscan2
- ERBIN | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as COSV99396038; called by muse, mutect2, varscan2
- ETS1 | c.1117A>G p.R373G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100090137; called by muse, mutect2, varscan2
- FAM111A | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100659334; called by muse, mutect2, varscan2
- FAM160A2 | c.2773G>A p.V925I (on ENST00000449352 / NM_001098794.2; = p.V939I on NM_032127.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV56413118, COSV99791771; called by muse, mutect2, varscan2
- FAM189A2 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs770184667, COSV99974759; called by muse, mutect2, varscan2
- FAM193A | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.274); catalogued as COSV100218686; called by muse, mutect2, varscan2
- FAM47A | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.787); catalogued as COSV100649755, COSV60496653; called by muse, mutect2, varscan2
- FAM76B | c.956A>G p.Q319R | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100716382; called by muse, mutect2, varscan2
- FAM83H | c.493A>G p.S165G | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1554623796, COSV101186924; called by muse, mutect2, varscan2
- FANCM | c.4016C>T p.T1339I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs1166545385, COSV99950565; called by muse, mutect2, varscan2
- FBN1 | c.7727G>A p.R2576H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs369888822, COSV57318792; called by muse, mutect2
- FLT3 | c.2317del p.R773Gfs*8 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs1566063342; called by mutect2, pindel, varscan2
- FLT4 | c.89dup p.T31Dfs*15 | Frame Shift Ins (INS) | VAF 30/114 reads (26%) | catalogued as rs755445139; called by mutect2, varscan2
- FN1 | c.6705C>G p.C2235W (on ENST00000359671 / NM_001365524.2; = p.C2204W on NM_002026.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100116304; called by muse, mutect2, varscan2
- FOXO1 | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs755827604, COSV65426228; called by muse, mutect2, varscan2
- FOXS1 | c.296A>G p.H99R | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV54067502; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- GDF9 | c.1097A>C p.K366T | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99737136; called by muse, mutect2, varscan2
- GFM1 | c.572+2T>C p.X191_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99962712; called by muse, mutect2, varscan2
- GGCT | c.88_89del p.R30Dfs*20 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | catalogued as rs748515382; called by pindel, varscan2
- GK2 | c.388dup p.I130Nfs*5 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | catalogued as rs771628988; called by mutect2, varscan2
- GLE1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as rs200439673, COSV59406407; called by muse, mutect2, varscan2
- GNAS | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV58328582; called by muse, mutect2, varscan2
- GNAS | c.2051A>G p.H684R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV100005510; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 31/93 reads (33%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GOLGB1 | c.8383A>G p.T2795A | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV100510389; called by muse, mutect2
- GON4L | c.2725A>G p.I909V | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99673534; called by muse, mutect2, varscan2
- GPR146 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.035); catalogued as rs367656590; called by muse, mutect2, varscan2
- GPSM2 | c.995A>G p.Y332C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV99915057; called by muse, mutect2, varscan2
- GRIN3A | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62451684; called by muse, mutect2, varscan2
- GRM1 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763886921, COSV51110227; called by muse, mutect2, varscan2
- GRM5 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100550540; called by muse, mutect2, varscan2
- HAO1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs768341358, COSV66491567; called by muse, mutect2, varscan2
- HELB | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1267788399, COSV56071957; called by muse, mutect2, varscan2
- HEXB | c.1322T>C p.F441S | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99714096; called by muse, mutect2, varscan2
- HEY2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.806); catalogued as rs769963246, COSV64239865; called by muse, mutect2, varscan2
- HHATL | c.288G>A p.K96= | Splice Region (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100124332; called by muse, mutect2, varscan2
- HIF1A | c.2177G>A p.G726D | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.215); catalogued as COSV60188210, COSV60189963; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.878-2A>T p.X293_splice (on ENST00000354667 / NM_031243.3; = p.X281_splice on NM_002137.4) | Splice Site (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100668215, COSV61158857; called by muse, mutect2, varscan2
- HTRA2 | c.346dup p.A116Gfs*22 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | catalogued as rs779457274; called by mutect2, varscan2
- HUWE1 | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99470842; called by muse, mutect2, varscan2
- IFNA8 | c.449T>C p.I150T | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101206882; called by muse, mutect2, varscan2
- IGSF22 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.532); catalogued as rs756471637, COSV60033649; called by muse, mutect2, varscan2
- IL17RD | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764856504, COSV99576647; called by muse, mutect2, varscan2
- INTU | c.1596G>T p.K532N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100080525; called by muse, mutect2, varscan2
- IQCB1 | c.100+2T>C p.X34_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60435443; called by muse, mutect2, varscan2
- IRF3 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs1370021596, COSV99880902; called by muse, mutect2, varscan2
- IRS4 | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1463218144, COSV100929450; called by muse, mutect2, varscan2
- JPH2 | c.2036T>C p.M679T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100881615; called by muse, mutect2
- KAT2A | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs782023771, COSV99863411; called by muse, mutect2, varscan2
- KCNIP2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV99493184; called by muse, mutect2, varscan2
- KIDINS220 | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV99875100; called by muse, mutect2, varscan2
- KIF15 | c.2813T>C p.V938A | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100392554; called by muse, mutect2, varscan2
- KLK1 | c.643G>T p.G215W | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100032547; called by muse, mutect2, varscan2
- KMT2D | c.10690C>T p.L3564F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99978139; called by muse, mutect2, varscan2
- KMT2D | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs767181879, COSV56410992; called by muse, mutect2, varscan2
- KPTN | c.1013A>C p.Y338S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99369698; called by muse, mutect2, varscan2
- KRT75 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52871913, COSV52875576; called by muse, mutect2
- KRTAP10-7 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1555928394, COSV100170027; called by muse, mutect2, varscan2
- KRTAP24-1 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as rs769750860, COSV61089510; called by muse, mutect2
- LAMA1 | c.2223_2224insA p.C742Mfs*2 | Frame Shift Ins (INS) | VAF 5/42 reads (12%) | catalogued as COSV101055277; called by mutect2, pindel, varscan2
- LBP | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201798672, COSV54143353, COSV99460454; called by muse, mutect2, varscan2
- LILRB2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs202197782, COSV58743809, COSV58747416; called by muse, mutect2, varscan2
- LMBR1L | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs765833111, COSV99918546; called by muse, mutect2, varscan2
- LMCD1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as COSV50090890, COSV99337285; called by muse, mutect2, varscan2
- LONP1 | c.2120G>A p.S707N | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100638535; called by muse, mutect2, varscan2
- LPAR2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs893509279, COSV99179097; called by muse, mutect2, varscan2
- LRGUK | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs376622972; called by muse, mutect2, varscan2
- LRP1 | c.5820C>G p.D1940E | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99674709; called by muse, mutect2, varscan2
- LRP2 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs763860226, COSV55542058; called by muse, mutect2, varscan2
- LRRK2 | c.7333A>T p.I2445L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV100109403; called by muse, mutect2, varscan2
- MACROH2A2 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100952304; called by muse, mutect2, varscan2
- MAFK | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs1322425045, COSV99867887; called by muse, mutect2
- MAP2K3 | c.124dup p.R42Pfs*17 (on ENST00000342679 / NM_145109.3; = p.R13Pfs*17 on NM_002756.4) | Frame Shift Ins (INS) | VAF 20/126 reads (16%) | catalogued as COSV100384541; called by mutect2, varscan2
- MAP3K5 | c.3302C>T p.T1101I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV100752555; called by muse, mutect2, varscan2
- MAPT | c.1514C>T p.A505V (on ENST00000262410 / NM_001377265.1; = p.A430V on NM_016835.4) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99289868; called by muse, mutect2, varscan2
- MARK1 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV100857078; called by muse, mutect2, varscan2
- MCF2L2 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs748817028, COSV100191526, COSV100192175; called by muse, mutect2, varscan2
- MCM2 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99412854; called by muse, mutect2, varscan2
- MELTF | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.228); catalogued as rs553886588, COSV56379550; called by muse, mutect2, varscan2
- MFF | c.593C>G p.T198S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.199); catalogued as COSV100449264; called by muse, mutect2, varscan2
- MICALL2 | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs767798767, COSV52518759; called by muse, mutect2
- MIS12 | c.608A>T p.K203I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV99342244; called by muse, mutect2, varscan2
- MKI67 | c.6917C>A p.P2306H | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV100896215; called by muse, mutect2, varscan2
- MNDA | c.47T>A p.L16H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.498); catalogued as COSV100933255; called by muse, mutect2, varscan2
- MNT | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.549); catalogued as COSV99437954; called by muse, mutect2
- MRPL30 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs771623578, COSV100585346; called by muse, mutect2, varscan2
- MRPL52 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100313956; called by muse, mutect2, varscan2
- MUC5B | c.3229C>T p.R1077C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747267448, COSV101500618, COSV71594286; called by muse, mutect2, varscan2
- MYB | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100214598; called by muse, mutect2, varscan2
- MYH1 | c.3206C>A p.S1069Y | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV56843664, COSV99875065; called by muse, mutect2, varscan2
- MYL6B | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as rs770630703, COSV52879281; called by muse, mutect2, varscan2
- MYO3A | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); catalogued as COSV99778573; called by muse, mutect2, varscan2
- NAV1 | c.1449del p.K483Nfs*9 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | catalogued as COSV55224089; called by mutect2, pindel, varscan2
- NAV2 | c.7403G>A p.S2468N (on ENST00000396087 / NM_001244963.2; = p.S2409N on NM_145117.5) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100216279; called by muse, mutect2, varscan2
- NBEA | c.1984A>G p.I662V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.847); catalogued as COSV100077267; called by muse, mutect2, varscan2
- NCF4 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99957124; called by muse, mutect2, varscan2
- NCK1 | c.976A>G p.K326E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99999365; called by muse, mutect2, varscan2
- NCOR2 | c.3407C>T p.P1136L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs766879930, COSV100656957; called by muse, mutect2, varscan2
- NEB | c.15064C>T p.R5022W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765006379, COSV99415919; called by muse, varscan2
- NEK9 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); catalogued as COSV99463610; called by muse, mutect2, varscan2
- NHS | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs745989162, COSV66277990; called by muse, mutect2, varscan2
- NINL | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99624728; called by muse, mutect2, varscan2
- NLGN2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV100192779; called by muse, mutect2, varscan2
- NPBWR2 | c.487dup p.A163Gfs*159 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | catalogued as rs757434354; called by mutect2, pindel, varscan2
- NPLOC4 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs778219768, COSV100480668; called by muse, mutect2, varscan2
- NPR1 | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as rs141668201; called by muse, mutect2, varscan2
- NR0B1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66764745; called by muse, mutect2, varscan2
- NT5DC2 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs769093251, COSV100194611; called by muse, mutect2, varscan2
- NTNG1 | c.1162A>G p.K388E | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV100903416; called by muse, mutect2, varscan2
- NYAP2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391805291, COSV55999732; called by muse, mutect2, varscan2
- OBI1 | c.1839del p.L614Sfs*9 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs1320199922; called by pindel, varscan2
- OLFM1 | c.815G>A p.R272H (on ENST00000371793 / NM_001282611.2; = p.R254H on NM_014279.5) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1325605984, COSV53276531; called by muse, mutect2, varscan2
- OR2M5 | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100822744; called by muse, mutect2, varscan2
- OR2W3 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100831609; called by muse, mutect2, varscan2
- OR4N5 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs1207709533, COSV100374038; called by muse, mutect2
- OR51E2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs757545384, COSV101211322, COSV101211398; called by muse, mutect2, varscan2
- OR5B12 | c.597dup p.V200Cfs*6 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | catalogued as rs747074822; called by mutect2, varscan2
- OR8B2 | c.672C>A p.S224R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); catalogued as COSV100899333; called by muse, mutect2, varscan2
- OXSR1 | c.1430G>T p.R477M | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV100309188; called by muse, mutect2
- P2RY8 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs762114324, COSV67177276; called by muse, mutect2, varscan2
- PAK3 | c.1316G>A p.G439E (on ENST00000262836 / NM_001324328.2; = p.G424E on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53277708; called by muse, mutect2, varscan2
- PARN | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100420703; called by muse, varscan2
- PCDHB1 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs149129886, COSV60629931; called by muse, mutect2
- PCNT | c.1855C>T p.H619Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV100855090; called by muse, mutect2, varscan2
- PCNX2 | c.5014C>T p.R1672C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs749244511, COSV99266307; called by muse, mutect2, varscan2
- PCSK6 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761780850, COSV59344277; called by muse, mutect2, varscan2
- PEAR1 | c.1688G>A p.C563Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99440747; called by muse, mutect2, varscan2
- PHKA2 | c.1859A>G p.D620G | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.282); catalogued as COSV101176740; called by muse, mutect2, varscan2
- PHKG1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768600789, COSV99304910; called by muse, mutect2, varscan2
- PIGR | c.1465T>C p.S489P | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV100732447; called by muse, mutect2
- PIK3C2B | c.1680dup p.C561Lfs*8 | Frame Shift Ins (INS) | VAF 15/120 reads (13%) | catalogued as COSV65814668; called by mutect2, pindel, varscan2
- PKHD1 | c.4930T>C p.W1644R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.073); catalogued as COSV100581460; called by muse, varscan2
- PKHD1 | c.4847T>C p.V1616A | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV100581461; called by muse, varscan2
- PKHD1L1 | c.1187del p.L396Wfs*33 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | catalogued as COSV65745671, COSV65750760; called by mutect2, pindel, varscan2
- PKN3 | c.756A>T p.R252S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99403305; called by muse, mutect2, varscan2
- PLA2G2F | c.284dup p.R96Pfs*7 | Frame Shift Ins (INS) | VAF 36/120 reads (30%) | catalogued as rs765044453; called by mutect2, pindel, varscan2
- PLCE1 | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1452138098, COSV99593761; called by muse, mutect2, varscan2
- PLCH1 | c.929T>C p.I310T (on ENST00000340059 / NM_001130960.2; = p.I322T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395783; called by muse, mutect2, varscan2
- PLXNA2 | c.2926G>A p.G976S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764102147, COSV100885197; called by muse, mutect2, varscan2
- PLXNA2 | c.271A>G p.N91D | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as COSV100885198; called by muse, mutect2, varscan2
- PML | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs147696900; called by muse, mutect2, varscan2
- PNPLA1 | c.770G>A p.R257Q (on ENST00000394571 / NM_001374623.1; = p.R162Q on NM_173676.2) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1173263480, COSV57237404; called by muse, mutect2, varscan2
- POLR2L | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as COSV100431704; called by muse, mutect2, varscan2
- POLR3A | c.2350G>A p.G784S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771786550, CM138021, COSV100965555; called by muse, mutect2, varscan2
- POSTN | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs201568682, COSV65713360; called by muse, mutect2, varscan2
- PPM1L | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377495364; called by muse, mutect2, varscan2
- PPRC1 | c.2111del p.G704Vfs*30 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as COSV99531679; called by mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 25/112 reads (22%) | catalogued as rs768056539; called by mutect2, varscan2
- PRDM1 | c.1300A>G p.I434V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100958585; called by muse, mutect2, varscan2
- PRDX5 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99134461; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PTPRT | c.3178A>G p.T1060A | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV100625573; called by muse, mutect2, varscan2
- PUM3 | c.1844C>A p.A615E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV101146272; called by muse, mutect2
- PWWP3B | c.1756T>A p.F586I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100530973; called by muse, mutect2, varscan2
- PXDN | c.2132C>A p.P711Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99412495; called by muse, mutect2, varscan2
- PXDNL | c.14T>C p.L5P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV100681822; called by muse, mutect2, varscan2
- PXMP2 | c.269_271del p.F90del | In Frame Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs745572613; called by pindel, varscan2
- RAB11FIP2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as rs1223867198, COSV100843000; called by muse, mutect2, varscan2
- RAB39B | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101034930; called by muse, mutect2, varscan2
- RAB8A | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99959695; called by muse, mutect2, varscan2
- RBM12 | c.2069C>T p.A690V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs188287954; called by muse, mutect2, varscan2
- RCC1L | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.295); catalogued as rs782713125, COSV57320388; called by muse, mutect2, varscan2
- RGS3 | c.2402C>A p.P801H (on ENST00000350696 / NM_001282923.2; = p.P520H on NM_130795.4) | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV100636577; called by muse, mutect2, varscan2
- RIMS2 | c.2897G>A p.G966E (on ENST00000666250 / NM_001348490.2; = p.G774E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.883); catalogued as COSV51705234; called by muse, mutect2, varscan2
- RNF148 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752847373, COSV57388876; called by muse, mutect2, varscan2
- RNFT2 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99985047; called by muse, mutect2, varscan2
- ROPN1B | c.305A>C p.D102A | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV99305481; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA1 | c.1104del p.S369Afs*18 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs745561139; called by mutect2, pindel, varscan2
- RRAGA | c.238A>G p.N80D | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV100998088; called by muse, mutect2, varscan2
- RUVBL2 | c.803T>A p.I268N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668843; called by muse, mutect2, varscan2
- RYR2 | c.11649A>G p.E3883= | Splice Region (SNP) | VAF 30/132 reads (23%) | catalogued as COSV100768382; called by muse, mutect2, varscan2
- RYR2 | c.13263A>G p.E4421= | Splice Region (SNP) | VAF 7/150 reads (5%) | catalogued as COSV100768383; called by muse, mutect2
- SAMD9 | c.582A>G p.I194M | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV101180139; called by muse, mutect2, varscan2
- SBF2 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99813355; called by muse, mutect2, varscan2
- SCRT2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV99856972; called by muse, mutect2, varscan2
- SELP | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.062); catalogued as rs143090272; called by muse, mutect2, varscan2
- SEMA3F | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99137237; called by muse, mutect2, varscan2
- SGTB | c.681+2T>C p.X227_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101121576; called by muse, mutect2, varscan2
- SH3PXD2B | c.2249C>A p.A750D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as rs1348936415, COSV100287709; called by muse, mutect2
- SLC25A20 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953809517, CM042779, COSV100033599; called by muse, mutect2, varscan2
- SLC26A6 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99372724; called by muse, mutect2, varscan2
- SLC26A7 | c.676G>C p.V226L | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as COSV99402670; called by muse, mutect2, varscan2
- SLC30A3 | c.279C>T p.G93= | Splice Region (SNP) | VAF 15/47 reads (32%) | catalogued as rs145366857, COSV51984415; called by muse, mutect2, varscan2
- SLC36A1 | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99695406; called by muse, mutect2, varscan2
- SLC47A2 | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100327866; called by muse, mutect2
- SLC6A6 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1364995487, COSV100691927; called by muse, mutect2, varscan2
- SLC9A5 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs781341421, COSV100237106; called by muse, mutect2, varscan2
- SLITRK1 | c.134dup p.F47Lfs*30 | Frame Shift Ins (INS) | VAF 9/22 reads (41%) | catalogued as rs763682501; called by mutect2, varscan2
- SMARCAD1 | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV100758776; called by muse, mutect2, varscan2
- SNRK | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV56067716; called by muse, mutect2, varscan2
- SP110 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.338); catalogued as COSV99283113; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | catalogued as rs746109620; called by mutect2, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | catalogued as rs750890082; called by mutect2, varscan2
- SPEN | c.7207A>C p.S2403R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV101005022; called by muse, mutect2, varscan2
- SPI1 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs770273178, COSV57044951; called by muse, mutect2, varscan2
- SPTBN4 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100150150; called by muse, mutect2, varscan2
- SPTBN4 | c.5413A>C p.M1805L | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100150155; called by muse, mutect2, varscan2
- STMN4 | c.400A>G p.N134D (on ENST00000265770 / NM_001283054.2; = p.N161D on NM_030795.4) | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV99740649; called by muse, mutect2, varscan2
- STYXL2 | c.1372A>G p.N458D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99608682; called by muse, mutect2, varscan2
- SUPT16H | c.2207C>T p.T736M | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV99359661; called by muse, mutect2, varscan2
- SUSD5 | c.1292T>C p.M431T | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1358013360, COSV100534946, COSV100534948; called by muse, mutect2, varscan2
- TACC2 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100551683; called by muse, varscan2
- TACC2 | c.4879G>A p.V1627M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV100551689; called by muse, mutect2, varscan2
- TAF1L | c.1994dup p.A666Gfs*38 | Frame Shift Ins (INS) | VAF 53/186 reads (28%) | catalogued as rs760628590; called by mutect2, varscan2
- TBC1D10B | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.149); catalogued as rs751916999, COSV59769406; called by muse, mutect2, varscan2
- TBC1D22B | c.670T>A p.S224T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV100996694; called by muse, mutect2, varscan2
- TBC1D31 | c.2938G>A p.A980T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV99782450; called by muse, mutect2, varscan2
- TBC1D5 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as rs760711564, COSV99509436; called by muse, varscan2
- TBC1D9 | c.3421C>T p.R1141W | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV101464278; called by muse, mutect2, varscan2
- TENM3 | c.3769G>A p.V1257I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as rs774602911, COSV101304641, COSV69306077; called by muse, mutect2, varscan2
- TFDP1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64742371; called by muse, mutect2, varscan2
- THBS1 | c.1769A>C p.D590A | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99527620; called by muse, mutect2, varscan2
- THNSL1 | c.2165T>C p.V722A | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV100896125; called by muse, mutect2
- TICRR | c.2127del p.K709Nfs*28 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as COSV51542075; called by mutect2, pindel, varscan2
- TIE1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); catalogued as rs1442012423, COSV65250701; called by muse, mutect2, varscan2
- TJP3 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53660916; called by muse, mutect2, varscan2
- TMEFF2 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99771118; called by muse, mutect2, varscan2
- TMEM184A | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs550093329, COSV52474782, COSV99867889; called by muse, mutect2
- TNN | c.2387A>G p.D796G | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99511230; called by muse, mutect2
- TNXB | c.6566A>G p.D2189G (on ENST00000647633; = p.D1942G on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100925967; called by muse, mutect2, varscan2
- TRIM27 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV101019233; called by muse, mutect2
- TRIM71 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV101070388; called by muse, mutect2, varscan2
- TRPM8 | c.2301dup p.E768Rfs*14 | Frame Shift Ins (INS) | VAF 42/105 reads (40%) | catalogued as rs770879940; called by mutect2, varscan2
- TRPV1 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99438885; called by muse, mutect2, varscan2
- TSSC4 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 35/77 reads (45%) | catalogued as COSV99329637; called by muse, mutect2, varscan2
- TTI1 | c.1874G>A p.W625* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as COSV100989588; called by muse, mutect2, varscan2
- TTLL8 | c.370A>G p.M124V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99838063; called by muse, mutect2, varscan2
- TUBGCP6 | c.3361G>A p.V1121M | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.27); catalogued as COSV99954928; called by muse, mutect2
- TUBGCP6 | c.1271G>A p.S424N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as COSV99954929; called by muse, mutect2, varscan2
- UBE2N | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.633); catalogued as COSV100538556, COSV100538637; called by muse, mutect2, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | catalogued as rs761528888; called by mutect2, varscan2
- VCP | c.1847del p.N616Mfs*63 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs751290466; called by mutect2, varscan2
- VDAC1 | c.321T>C p.T107= | Splice Region (SNP) | VAF 25/59 reads (42%) | catalogued as rs1381208759, COSV99527166; called by muse, mutect2, varscan2
- WDR11 | c.3632T>C p.L1211S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as rs771157292, COSV99676306; called by muse, mutect2, varscan2
- WDR17 | c.3560A>G p.Y1187C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54577246; called by muse, mutect2, varscan2
- WNT9A | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99688055; called by muse, mutect2, varscan2
- WWP2 | c.2576A>G p.Y859C | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100598451; called by muse, mutect2, varscan2
- ZBTB3 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs750718381, COSV101188936; called by muse, mutect2, varscan2
- ZBTB43 | c.1093G>T p.G365* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100991301; called by muse, mutect2
- ZBTB7B | c.1540A>G p.T514A (on ENST00000292176; = p.T548A on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.018); catalogued as COSV99420856; called by muse, mutect2
- ZCWPW1 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs199651585, COSV100228065; called by muse, mutect2, varscan2
- ZFC3H1 | c.4181T>C p.L1394S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101110358; called by muse, mutect2, varscan2
- ZNF112 | c.521A>T p.Y174F (on ENST00000337401 / NM_001083335.2; = p.Y168F on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100495514, COSV61619669; called by muse, mutect2, varscan2
- ZNF234 | c.1079A>C p.Q360P | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.69); catalogued as COSV101468337, COSV70603549; called by muse, mutect2, varscan2
- ZNF263 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV99526736; called by muse, mutect2, varscan2
- ZNF385D | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as COSV99873603; called by muse, mutect2, varscan2
- ZNF432 | c.611del p.N204Tfs*45 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | catalogued as rs1438216527; called by mutect2, pindel, varscan2
- ZNF740 | c.8A>G p.Q3R | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.403); catalogued as COSV99914536; called by muse, mutect2, varscan2
- ZNF862 | c.2360T>C p.V787A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV99783246; called by muse, mutect2, varscan2
- ZP4 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100850603; called by muse, mutect2
- ZXDB | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.727); catalogued as rs1303165996, COSV100885800; called by muse, mutect2, varscan2
- AFG3L2 | c.255del p.A86Lfs*99 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- ATAD5 | c.3579del p.F1193Lfs*6 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- C2orf42 | c.1230del p.K410Nfs*38 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- CAAP1 | c.575dup p.L192Ffs*5 | Frame Shift Ins (INS) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- CCDC160 | c.51del p.F17Lfs*7 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | called by mutect2, pindel, varscan2
- CCDC59 | c.709del p.I237Yfs*13 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- CCDC88A | c.2335dup p.I779Nfs*7 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | called by mutect2, varscan2
- CDH11 | c.1292del p.F431Sfs*142 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- CDH8 | c.1047del p.K349Nfs*5 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- CKAP5 | c.1634del p.K545Rfs*38 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- CNTN3 | c.459_460del p.S154Ifs*7 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- DHX9 | c.3763del p.A1255Pfs*63 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- DYNC1LI1 | c.1288dup p.I430Nfs*2 | Frame Shift Ins (INS) | VAF 27/91 reads (30%) | called by mutect2, varscan2
- FAM117A | c.900del p.N301Tfs*63 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- GLI3 | c.3098del p.P1033Rfs*46 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- GRID2 | c.2686dup p.S896Ffs*6 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- IL20RA | c.398del p.L133* | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- JAK1 | c.1623del p.K541Nfs*30 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- KMT2D | c.9265del p.V3089Wfs*30 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- MAP3K8 | c.1325_1326del p.R442Lfs*23 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- MAP9 | c.739_741dup p.S247dup | In Frame Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- MTBP | c.381del p.F127Lfs*40 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | called by mutect2, varscan2
- NLRP3 | c.2453_2454del p.V818Gfs*57 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | called by pindel, varscan2
- OR11H4 | c.125dup p.L42Ffs*39 | Frame Shift Ins (INS) | VAF 35/125 reads (28%) | called by mutect2, pindel, varscan2
- PCDHGA8 | c.916dup p.S306Kfs*5 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- PELP1 | c.1440dup p.S481Efs*3 | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | called by mutect2, varscan2
- PLAT | c.136del p.T46Rfs*3 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- PLXNA3 | c.1216del p.L406Cfs*32 | Frame Shift Del (DEL) | VAF 38/121 reads (31%) | called by mutect2, pindel, varscan2
- PPP1R10 | c.2815del p.L939Cfs*109 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- PRPF4B | c.2340dup p.Y781Ifs*3 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | called by mutect2, varscan2
- PSMD1 | c.372del p.K124Nfs*11 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, varscan2
- PTEN | c.582_584del p.L194del | In Frame Del (DEL) | VAF 7/42 reads (17%) | called by pindel, varscan2
- RACK1 | c.342_344del p.S115del | In Frame Del (DEL) | VAF 30/97 reads (31%) | called by pindel, varscan2
- RBM27 | c.3125del p.L1042Cfs*22 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- RERE | c.4009del p.L1337Cfs*35 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- ROS1 | c.904dup p.R302Kfs*11 | Frame Shift Ins (INS) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- SERPINI2 | c.278del p.F93Sfs*27 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- SLC2A14 | c.293del p.G98Vfs*2 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | called by mutect2, pindel, varscan2
- SLC38A1 | c.919del p.M307Cfs*18 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- SLC52A3 | c.882del p.C295Afs*88 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- SMARCA1 | c.1037del p.N346Tfs*46 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | called by mutect2, pindel, varscan2
- SREK1 | c.723del p.K241Nfs*34 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- SYNCRIP | c.854del p.N285Tfs*22 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, varscan2
- TMPRSS3 | c.1033del p.A345Pfs*13 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- TPTE | c.745_746del p.M249Vfs*12 (on ENST00000618007 / NM_199261.4; = p.M231Vfs*12 on NM_199259.4) | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | called by mutect2, pindel, varscan2
- UBR2 | c.1821del p.V608Lfs*18 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- UPF1 | c.1111del p.D371Mfs*46 (on ENST00000599848 / NM_001297549.2; = p.D360Mfs*46 on NM_002911.4) | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- USP51 | c.1904_1906del p.E635del | In Frame Del (DEL) | VAF 16/34 reads (47%) | called by pindel, varscan2
- WDR5 | c.648del p.V217Cfs*4 | Frame Shift Del (DEL) | VAF 42/128 reads (33%) | called by mutect2, varscan2
- ZDHHC17 | c.809del p.N270Mfs*4 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- ZNF442 | c.658del p.W220Gfs*34 | Frame Shift Del (DEL) | VAF 28/136 reads (21%) | called by mutect2, pindel, varscan2
- ZNF544 | c.1302del p.K434Nfs*46 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- ZNF605 | c.997G>T p.G333W | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM17 | c.1680T>C p.N560= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV100176078; called by muse, mutect2, varscan2
- ADCYAP1 | c.336C>T p.G112= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV99327458; called by muse, mutect2, varscan2
- ADGRF2 | c.2058T>C p.N686= (on ENST00000296862 / NM_001368115.2; = p.N618= on NM_153839.7) | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs774737692, COSV99730794; called by muse, mutect2, varscan2
- ALDH1A1 | c.975G>A p.E325= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99921109; called by muse, mutect2
- ANXA11 | c.699G>A p.K233= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV99626869; called by muse, mutect2, varscan2
- APOB | c.7752G>A p.G2584= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1290144717, COSV99263949; called by muse, mutect2, varscan2
- ARHGAP32 | c.4434G>A p.R1478= (on ENST00000310343 / NM_001378025.1; = p.R1129= on NM_014715.4) | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as rs1565345996, COSV100087068; called by muse, mutect2, varscan2
- ARHGAP5 | c.4161C>T p.Y1387= (on ENST00000345122 / NM_001030055.2; = p.Y1386= on NM_001173.3) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs776001609, COSV53734985; called by muse, mutect2, varscan2
- AS3MT | c.819T>A p.V273= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100185580; called by muse, mutect2, varscan2
- ATP10B | c.2892T>C p.R964= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100514288; called by muse, mutect2, varscan2
- ATP11A | c.1470C>T p.D490= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs746797753, COSV99367627; called by muse, mutect2, varscan2
- BACH2 | c.1692A>G p.P564= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV99998274; called by muse, mutect2, varscan2
- BANP | c.1350G>A p.L450= (on ENST00000286122; = p.L400= on NM_017869.4) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1438168160, COSV99620905; called by muse, mutect2
- BCR | c.1254C>T p.G418= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1215387582, COSV100006049; called by muse, mutect2, varscan2
- BRPF3 | c.1464T>C p.C488= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100325600; called by muse, mutect2, varscan2
- BSN | c.7168C>T p.L2390= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99607447; called by muse, mutect2, varscan2
- C15orf39 | c.2346C>T p.V782= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs373873430; called by muse, mutect2, varscan2
- CACNA1E | c.99G>A p.S33= | Silent (SNP) | VAF 34/166 reads (20%) | catalogued as rs769667152, COSV100701375; called by muse, mutect2, varscan2
- CALU | c.663T>C p.D221= | Silent (SNP) | VAF 12/165 reads (7%) | catalogued as COSV99975499; called by muse, mutect2
- CAND2 | c.891G>A p.V297= (on ENST00000456430 / NM_001162499.2; = p.V204= on NM_012298.3) | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as COSV55993009, COSV99928693; called by muse, mutect2, varscan2
- CAPSL | c.582T>C p.T194= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV101274188; called by muse, mutect2, varscan2
- CARS1 | c.1122T>C p.H374= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99542117; called by muse, mutect2, varscan2
- CASZ1 | c.5088C>T p.D1696= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100985067; called by muse, varscan2
- CCBE1 | c.477C>T p.C159= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs149268172; called by muse, mutect2, varscan2
- CHD5 | c.4434G>A p.P1478= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as rs1248246974, COSV52419923; called by muse, varscan2
- CHDH | c.228C>T p.D76= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs748590360, COSV100179590; called by muse, mutect2, varscan2
- CHRNA4 | c.669C>T p.Y223= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs79068736, COSV100937361; ClinVar: likely benign; called by muse, mutect2
- CIITA | c.1593C>A p.G531= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100161463; called by muse, mutect2, varscan2
- COL12A1 | c.9165C>T p.N3055= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs369646700; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRB1 | c.978C>T p.H326= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100958419; called by muse, mutect2, varscan2
- CSMD3 | c.1155C>A p.V385= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV99826498; called by muse, mutect2, varscan2
- CWH43 | c.1353T>C p.A451= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99892908; called by muse, mutect2, varscan2
- CYP2S1 | c.933C>T p.V311= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs137941427; called by muse, mutect2, varscan2
- DDX21 | c.1467A>G p.G489= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV100826475; called by muse, mutect2, varscan2
- DDX51 | c.1593C>T p.D531= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs769510259, COSV57957601; called by muse, mutect2, varscan2
- DEPDC1B | c.624C>T p.D208= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs200675292, COSV54012085, COSV99409767; called by muse, mutect2, varscan2
- DKK1 | c.264C>T p.D88= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs1457993160, COSV100906486; called by muse, mutect2, varscan2
- DRC7 | c.1800G>A p.A600= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs1469146186, COSV100395401; called by muse, mutect2, varscan2
- DSG2 | c.2274C>T p.A758= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs778950229, COSV99852822, COSV99853588; called by muse, mutect2, varscan2
- E2F7 | c.2217G>A p.P739= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs376673165; called by muse, mutect2
- EPS8L2 | c.280C>T p.L94= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs1476828372, COSV100585351; called by muse, mutect2, varscan2
- EXTL1 | c.576C>T p.P192= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs746776616, COSV100959061; called by muse, mutect2, varscan2
- FBXO24 | c.402C>T p.H134= (on ENST00000241071 / NM_033506.3; = p.H172= on NM_012172.5) | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs766451108, COSV53825075; called by muse, mutect2, varscan2
- FCGR2B | c.525C>T p.S175= | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as rs1402947136, COSV99374885; called by muse, mutect2, varscan2
- FGD2 | c.1503C>T p.Y501= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs374359730; called by muse, mutect2, varscan2
- FYCO1 | c.1071A>G p.S357= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV56115770; called by muse, mutect2, varscan2
- GABRG2 | c.1458G>A p.R486= (on ENST00000361925 / NM_001375343.1; = p.R446= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV100729593, COSV100729651; called by muse, mutect2, varscan2
- GSDMD | c.1170G>A p.A390= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs147170827; called by muse, mutect2, varscan2
- H3C6 | c.291C>T p.C97= | Silent (SNP) | VAF 67/241 reads (28%) | catalogued as COSV64519830; called by muse, mutect2, varscan2
- HYOU1 | c.2907T>C p.T969= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV101345548; called by muse, mutect2
- IFI27 | c.183C>A p.I61= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV100108326, COSV54141051; called by muse, mutect2, varscan2
- IGLV3-10 | c.174A>G p.S58= | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- IL13 | c.342C>T p.S114= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV100449388; called by muse, mutect2, varscan2
- INPP5A | c.213C>T p.F71= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs570568882, COSV61248433; called by muse, mutect2, varscan2
- KANK2 | c.99C>T p.S33= | Silent (SNP) | VAF 6/134 reads (4%) | catalogued as rs1215800099, COSV62008842; called by muse, mutect2
- KCNN2 | c.27C>A p.G9= (on ENST00000264773; = p.G221= on NM_021614.4) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV53293270, COSV99298888; called by muse, mutect2
- LAMA2 | c.1275C>A p.V425= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV101370181; called by muse, mutect2, varscan2
- LAMC2 | c.222G>A p.R74= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV51456612; called by muse, mutect2, varscan2
- LPA | c.1020C>T p.A340= | Silent (SNP) | VAF 14/320 reads (4%) | catalogued as rs758742474; called by muse, mutect2
- LRFN5 | c.666A>G p.L222= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV99982722; called by muse, mutect2, varscan2
- LRP1 | c.1884C>T p.S628= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs202138736; called by muse, mutect2, varscan2
- LRP5 | c.2697C>T p.R899= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV99591522; called by muse, mutect2, varscan2
- LY6K | c.441G>A p.L147= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV99456144; called by muse, mutect2, varscan2
- MACO1 | c.570C>T p.N190= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs774408245, COSV65478244; called by muse, mutect2, varscan2
- MAP4K1 | c.1128G>A p.S376= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs766596701, COSV67708637; called by muse, mutect2, varscan2
- MDH1 | c.225C>T p.D75= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs748664587, COSV99250860; called by muse, mutect2, varscan2
- MORC1 | c.1803C>T p.G601= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs767341013, COSV51715855, COSV51723547; called by muse, mutect2, varscan2
- MRC2 | c.898T>C p.L300= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV100315871; called by muse, mutect2, varscan2
- MTA1 | c.1530C>T p.A510= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as rs371437166; called by muse, mutect2
- MYO9B | c.2043C>T p.A681= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs376578647; called by muse, mutect2, varscan2
- N4BP3 | c.126T>C p.P42= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99200610; called by muse, mutect2, varscan2
- NDUFA11 | c.414A>G p.K138= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as COSV99398559; called by muse, mutect2, varscan2
- NEK9 | c.228A>G p.S76= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99463613; called by muse, mutect2, varscan2
- NFAT5 | c.3801C>T p.S1267= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100590510; called by muse, mutect2, varscan2
- NID1 | c.2913G>A p.A971= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs750878544, COSV99937066; called by muse, mutect2, varscan2
- NID1 | c.2712C>T p.R904= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV99937067; called by muse, mutect2
- NPM3 | c.138C>T p.H46= | Silent (SNP) | VAF 34/166 reads (20%) | catalogued as rs1339797753, COSV100761670; called by muse, mutect2, varscan2
- OBSCN | c.16272C>A p.T5424= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs770215470, COSV99473838, COSV99480025; called by muse, mutect2, varscan2
- OPTC | c.330T>C p.P110= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV100921734; called by muse, mutect2, varscan2
- OXTR | c.393G>A p.L131= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100373054; called by muse, mutect2, varscan2
- PABPC3 | c.180G>A p.Q60= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV99879086; called by muse, mutect2, varscan2
- PCDH15 | c.5454T>C p.L1818= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV100216234; called by muse, mutect2, varscan2
- PCDHB16 | c.2238C>A p.S746= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as COSV99501279; called by muse, mutect2, varscan2
- PCOLCE2 | c.786T>C p.I262= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV99930402; called by muse, varscan2
- POLN | c.2073G>A p.E691= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV101242479; called by muse, mutect2, varscan2
- PPM1K | c.516G>A p.S172= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1230975459, COSV55797593, COSV99900834; called by muse, mutect2, varscan2
- PPP2R3A | c.1065T>C p.N355= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs200377717, COSV99386551; called by muse, mutect2, varscan2
- PRRC2C | c.2796C>T p.N932= (on ENST00000367742; = p.N930= on NM_015172.4) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100144759; called by muse, mutect2
- RAB18 | c.243A>G p.A81= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV100803785; called by muse, mutect2, varscan2
- RAB3B | c.585G>A p.P195= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs780152564, COSV100862455; called by muse, mutect2, varscan2
- RABL3 | c.540C>T p.C180= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99846374; called by muse, mutect2, varscan2
- RHBDD3 | c.6T>C p.H2= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV99328436; called by muse, mutect2, varscan2
- RNF103 | c.1407G>A p.P469= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs201951625, COSV99409968; called by muse, mutect2, varscan2
- RRM1 | c.150G>T p.G50= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100331243; called by muse, mutect2, varscan2
- RRP12 | c.1404T>C p.V468= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs751344563, COSV100212958; called by muse, mutect2, varscan2
- SAP130 | c.1686G>A p.Q562= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV99384178; called by muse, mutect2, varscan2
- SCN7A | c.4971C>T p.D1657= | Silent (SNP) | VAF 3/52 reads (6%) | catalogued as COSV101313105; called by muse, mutect2
- SHROOM4 | c.3411G>A p.E1137= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs781966917, COSV56785285; called by muse, mutect2, varscan2
- SKIL | c.561T>C p.C187= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs781114604, COSV99378090; called by muse, varscan2
- SLC13A2 | c.1239G>A p.V413= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs978933460, COSV100120156; called by muse, mutect2, varscan2
- SLC22A14 | c.1560G>A p.L520= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV99828123; called by muse, mutect2, varscan2
- SLC2A4RG | c.631C>T p.L211= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99828817; called by muse, mutect2, varscan2
- SLC4A7 | c.30A>G p.L10= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs974953823, COSV99839271; called by muse, mutect2, varscan2
- SLCO3A1 | c.1134G>A p.Q378= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100574987; called by muse, mutect2, varscan2
- SMOX | c.555C>T p.D185= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs777935818, COSV99602893; called by muse, mutect2, varscan2
- SOS2 | c.3154T>C p.L1052= | Silent (SNP) | VAF 59/146 reads (40%) | catalogued as COSV99365488; called by muse, mutect2, varscan2
- SPATA31A3 | c.201G>A p.G67= | Silent (SNP) | VAF 117/358 reads (33%) | called by muse, mutect2, varscan2
- SPNS1 | c.861G>A p.T287= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as COSV100208943; called by muse, mutect2, varscan2
- SRCAP | c.5988T>A p.P1996= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs1230782914, COSV99349451; called by muse, mutect2, varscan2
- STXBP6 | c.387C>A p.T129= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as COSV100121564; called by muse, mutect2
- SUPT16H | c.2574A>G p.V858= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99359659; called by muse, mutect2, varscan2
- SUV39H1 | c.1167T>C p.P389= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV100551695; called by muse, mutect2, varscan2
- TACC2 | c.2010G>A p.L670= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100551687; called by muse, varscan2
- TBXAS1 | c.879C>T p.G293= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs781191549, COSV54956784; called by muse, mutect2, varscan2
- TEX15 | c.7113A>G p.V2371= (on ENST00000256246; = p.V2754= on NM_001350162.2) | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV99820808; called by muse, mutect2, varscan2
- THSD1 | c.1302G>A p.T434= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs751283275, COSV51627988; called by muse, mutect2, varscan2
- TLE4 | c.375G>T p.L125= | Silent (SNP) | VAF 94/214 reads (44%) | catalogued as COSV99511354; called by muse, mutect2, varscan2
- TMC3 | c.2649C>T p.H883= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs773031062, COSV63923373, COSV63923707; called by muse, mutect2, varscan2
- TMEM127 | c.651C>T p.N217= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs759801591, COSV99302494; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM130 | c.288C>T p.V96= | Silent (SNP) | VAF 58/114 reads (51%) | catalogued as rs1554400112, COSV100228572; called by muse, mutect2
- TMEM215 | c.402C>A p.S134= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100713140; called by muse, mutect2, varscan2
- TNXB | c.9507C>T p.G3169= (on ENST00000647633; = p.G2922= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV100925966; called by muse, mutect2, varscan2
- TRABD | c.324C>T p.C108= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as COSV100326717; called by muse, mutect2, varscan2
- TTN | c.45957G>A p.E15319= (on ENST00000591111; = p.E7895= on NM_003319.4) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV100597379; called by muse, mutect2, varscan2
- USP35 | c.1677G>A p.P559= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs544472594, COSV101489043; called by muse, mutect2, varscan2
- USP5 | c.2040G>A p.T680= (on ENST00000229268 / NM_001098536.2; = p.T657= on NM_003481.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs782066186, COSV57539685, COSV99978247; called by muse, mutect2, varscan2
- VPS13B | c.9129A>T p.A3043= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100660975; called by muse, mutect2
- ZBTB41 | c.2454T>C p.P818= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as rs1353801064, COSV100962884; called by muse, mutect2, varscan2
- ZNF407 | c.5790C>T p.L1930= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1282410677, COSV100224915; called by muse, mutect2, varscan2
- ZNF598 | c.1173C>A p.R391= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV101461931; called by muse, mutect2, varscan2
- ZNF696 | c.414G>A p.S138= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs762681691, COSV100350411; called by muse, mutect2, varscan2
- ZNF765 | c.735C>T p.C245= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as rs778760864, COSV67182050; called by muse, mutect2, varscan2
- ACAD9 | c.*47C>A | 3'UTR (SNP) | VAF 24/76 reads (32%) | catalogued as rs772433732, COSV100458977; called by muse, mutect2, varscan2
- CKAP5 | c.4027+164G>A | Intron (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100370480; called by muse, mutect2, varscan2
- CNR2 | c.-1del | 5'UTR (DEL) | VAF 9/27 reads (33%) | called by mutect2, varscan2
- CTSE | c.*29T>A | 3'UTR (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100733500; called by muse, mutect2, varscan2
- FOLH1B | n.1541_1542del | RNA (DEL) | VAF 32/106 reads (30%) | called by pindel, varscan2
- H2BC3 | c.-1A>G | 5'UTR (SNP) | VAF 15/74 reads (20%) | catalogued as rs1405741720; called by muse, mutect2, varscan2
- MASP1 | c.1303+4971G>A | Intron (SNP) | VAF 16/65 reads (25%) | catalogued as rs147966392, COSV56228175, COSV99962853; called by muse, mutect2, varscan2
- MIR519A1 | n.10T>C | RNA (SNP) | VAF 58/158 reads (37%) | called by muse, mutect2, varscan2
- MPZ | c.-20C>T | 5'UTR (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100337808; called by muse, mutect2, varscan2
- NDUFV3 | c.170-4684G>T | Intron (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100446927; called by muse, mutect2, varscan2
- NSUN5 | c.*102G>A | 3'UTR (SNP) | VAF 94/222 reads (42%) | catalogued as rs782786125, COSV99392227; called by muse, mutect2, varscan2
- POLA1 | c.2549-841_2549-840dup | Intron (INS) | VAF 15/38 reads (39%) | called by mutect2, varscan2
- POLA1 | c.2947-21392T>C | Intron (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- SCRIB | c.643-28C>T | Intron (SNP) | VAF 29/100 reads (29%) | catalogued as rs559575765, COSV100252686; called by muse, mutect2, varscan2
- SIGLEC7 | c.-1T>C | 5'UTR (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99978491; called by muse, mutect2, varscan2
- SLC25A3 | c.645-80G>A | Intron (SNP) | VAF 35/82 reads (43%) | catalogued as COSV51846420; called by muse, mutect2, varscan2
- TRAV36DV7 | chr14:22222277 A>G | 5'Flank (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
